Gene-level copy-number profile of tumor specimen C3N-01521-01 from CPTAC case C3N-01521, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 75.8 years (27,702 days).
Specimen C3N-01521-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e9a2d2fb-b3cf-4231-9c11-a5aa7a299a50.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01521-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/08033da6-330a-49c3-859e-9f76bfe748ec

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 18,071; copy number 2: 35,018; copy number 3: 4,083; copy number 4: 386; copy number 5: 648; copy number 6: 179; copy number 7: 3; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,945,756–181,006,727, 5 genes (within-gene range 0–1): RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr11:63,115,880–63,116,338, 1 gene (within-gene range 0–2): RPL29P22.
- chr22:18,906,028–18,947,732, 3 genes (within-gene range 0–1): DGCR6, AC007326.4, PRODH.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 831 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,699,619, 12 genes, copy number 6: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17.
- chr3:121,431,427–121,749,767, 8 genes, copy number 5: POLQ, RPL7AP11, ARGFX, FBXO40, HCLS1, RN7SL172P, RNU4-62P, GOLGB1.
- chr7:74,796,144–74,897,835, 4 genes, copy number 5: GTF2IRD2, STAG3L2, PMS2P5, Y_RNA.
- chr7:141,551,278–141,812,257, 16 genes, copy number 5 (within-gene range 3–5): AGK, AC004918.1, DENND11, AC004918.3, WEE2-AS1, WEE2, RNU1-82P, SSBP1, TAS2R3, TAS2R4, TAS2R6P, TAS2R5, MTCO1P55, MTND2P5, MTND1P3, MYL6P4.
- chr8:95,986,108–145,066,685, 758 genes, copy number 5–6 (within-gene range 5–7) (broad region; genes not listed).
- chr11:3,410,352–3,531,328, 4 genes, copy number 5 (within-gene range 2–5): FAM86GP, AC127526.3, AC127526.1, AC127526.5.
- chr11:3,797,724–4,093,210, 12 genes, copy number 5 (within-gene range 2–5): PGAP2, RHOG, STIM1-AS1, STIM1, AC090587.1, MIR4687, PPIAP40, AC087441.1, AC087441.3, HNRNPA1P76, AC087441.2, RPS29P20.
- chr11:8,980,576–9,004,049, 1 gene, copy number 6: NRIP3.
- chr11:13,826,843–14,643,635, 13 genes, copy number 5–9 (within-gene range 4–9): AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1.
- chr11:69,641,156–69,704,022, 3 genes, copy number 7: CCND1, LTO1, FGF19.

Autosomal genes at a single copy (total copy number 1): 17,545. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
